Surgical pathology report (de-identified scan), TCGA case TCGA-G9-7521, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G9-7521-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

- A. LEFT PELVIC LYMPH NODES
- B. RIGHT PELVIC LYMPH NODES
- C. PROSTATE

SPECIMEN(S):

- A. LEFT PELVIC LYMPH NODES
- B. RIGHT PELVIC LYMPH NODES
- C. PROSTATE

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSA-left pelvic lymph nodes: Positive for carcinoma (2 foci in 1 lymph node measuring 1 mm and < 2 mm).

FSB-right pelvic lymph nodes: Negative for carcinoma.

Diagnosis called by

DIAGNOSIS:

- A. LYMPH NODES, LEFT PELVIC, DISSECTION:
- METASTATIC CARCINOMA INVOLVING ONE LYMPH NODE (1/4).
- NO EXTRACAPSULAR EXTENSION PRESENT.

- B. LYMPH NODES, RIGHT PELVIC, DISSECTION:
- FIVE BENIGN LYMPH NODES (0/5).

- C. PROSTATE, RADICAL PROSTATECTOMY:
- PROSTATE ADENOCARCINOMA, GLEASON'S GRADE 4+4 (8/10), TERTIARY GRADE 5, INVOLVING APPROXIMATELY 11% OF THE EXAMINED GLAND.
- EXTENSIVE LYMPHOVASCULAR AND EXTRAPROSTATIC INVOLVEMENT.
- SURGICAL MARGINS AND SEMINAL VESICLES ARE NOT INVOLVED.

SYNOPTIC REPORT - PROSTATE GLAND

Specimens Involved

Specimens: A: LEFT PELVIC LYMPH NODES

C: PROSTATE

Location: Left

Right

Posterior lateral

Basal

Anterior

WHO CLASSIFICATION

Epithelial tumors

Adenocarcinoma 8140/3

Multicentricity: Yes

Gland Involvement: 11%

Gleason Grade/Sum:: Grade 4 + 4 , Sum 8 /10; Tertiary grade 5

High Grade PIN Present: No

Perineural Invasion: Yes

Vascular/Lymphatic Invasion: Yes

Seminal Vesicle Invasion: No

Periprostatic Fat Involved: Yes

Details: left anterior and mid base

Bladder Neck Involved: No

Margins Involvement: No

Frozen Performed: Yes

Lymph Nodes: Positive Right 0 / 5 Left 1 / 4

Other Pathologic Findings: None identified

Pathological Staging (pTNM): T 3a N 1 M x

Pathological staging is based on the AJCC Cancer Staging Manual, 7th Edition

[page 2 of 2]
GROSS DESCRIPTION:

A. LEFT PELVIC LYMPH NODES

Received fresh labeled with the patient's identification "left pelvic LN" is an aggregate of soft tissue, 5 x 2 x 1.5 cm containing multiple lymph nodes; lymph nodes are submitted entirely for frozen section diagnosis:

FSA: frozen section of 1 lymph node sectioned

FSA2: frozen section of multiple lymph nodes

B. RIGHT PELVIC LYMPH NODES

Received fresh labeled with the patient's identification and "right pelvic LN" is an aggregate of soft tissue, 5 x 4 x 1.5 cm containing multiple lymph nodes; lymph nodes are submitted entirely for frozen section diagnosis:

FSB1: frozen section of 1 lymph node, sectioned

FSB2: frozen section of multiple lymph nodes

C. PROSTATE

Received fresh labeled with the patient's identification and "prostate" is a 44 g resected prostate gland measuring 5.1 cm from right lateral to left lateral, 4.2 cm from anterior to posterior, and 2.9 cm from apex to base. Capsule is slightly nodular, red, and intact. Ink codes: base-blue, apex-red, anterior-orange, right lateral-green, left lateral-yellow, and posterior-black. After removal of apex and base, the prostate weighs 25 g and has a nodular tan parenchyma. The right seminal vesicle is 2.7 x 1.5 x 0.8 cm and the left is 3.2 x 1.7 x 0.8 cm; they consist of cystic tan tissue. The right vas deferens is 3.7 x 0.7 cm and the left is 2.9 x 0.6 cm; they consist of tubular tan tissue. Tissue is procured (13 g; the submitted entirely:

C1-C3: perpendicular sections of apex submitted clockwise from right anterior

C4: level 1, right anterior

C5: level 1, right posterior

C6: level 1, left anterior

C7: level 1, left posterior

C8: level 2, right lateral and posterior capsule

C9: level 2, left lateral and anterior capsule

C10: level 3, right anterior

C11: level 3, right posterior

C12: level 3, left anterior

C13: level 3, left posterior

C14-C15: perpendicular sections of right mid base

C16-C17: perpendicular sections of left mid base

C18-C19: perpendicular sections of right lateral base

C20-C21: perpendicular sections of left lateral base

C22: perpendicular sections of right posterior base

C23: perpendicular sections of left posterior base

C24: perpendicular sections of right mid base urethral orifice

C25: perpendicular sections of left mid base urethral orifice

C26: right seminal vesicle and vas deferens

C27: left seminal vesicle and vas deferens

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Prostate cancer

Microscopic/Diagnostic Dictation: [REDACTED]

Microscopic/Diagnostic Dictation: PATHOLOGIST, [REDACTED]

Final Review: PATHOLOGIST, [REDACTED]

Final: PATHOLOGIST, [REDACTED]

Source: NCI Genomic Data Commons file 9ca80c63-672f-4e6e-bac1-9809693f5f81 (TCGA-G9-7521.B0A188E3-C084-4E2D-93DD-31DE3A3F47E6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).